Somatic mutation profile of tumor specimen MP2PRT-PATIVJ-TMP1-A (aliquot MP2PRT-PATIVJ-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PATIVJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.3 years (3,386 days).
Specimen MP2PRT-PATIVJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0dd085a4-7a3d-4a13-8527-b4eeeedfa768.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATIVJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATIVJ-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/800a7d7e-6099-4ba0-b721-7023a2017135

The open-access MAF lists 127 somatic variants for this specimen: 86 protein-altering or splice-affecting, 39 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 39, Nonsense Mutation 4, Splice Site 2, Intron 2, Frame Shift Ins 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 124/338 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB4 | c.2789C>T p.S930F | Missense Mutation (SNP) | VAF 79/211 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV55935848; called by muse, mutect2, varscan2
- ACTL6A | c.1130G>T p.R377L | Missense Mutation (SNP) | VAF 78/200 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV52022999; called by muse, mutect2, varscan2
- CDH11 | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 112/255 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs746370506, COSV51766892; called by muse, mutect2, varscan2
- CREBBP | c.4862T>G p.L1621R | Missense Mutation (SNP) | VAF 225/484 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52113469; called by muse, mutect2, varscan2
- CSMD1 | c.4240G>A p.V1414I (on ENST00000520002; = p.V1413I on NM_033225.6) | Missense Mutation (SNP) | VAF 150/407 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs527352928; called by muse, mutect2, varscan2
- CTNNA2 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 107/258 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as COSV58173470; called by muse, mutect2, varscan2
- CUBN | c.8233G>A p.D2745N | Missense Mutation (SNP) | VAF 125/304 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs886046865, COSV64717959; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDX10 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1366255072, COSV59432897; called by muse, mutect2, varscan2
- DYSF | c.4548G>T p.E1516D | Missense Mutation (SNP) | VAF 108/317 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV50531302; called by muse, mutect2, varscan2
- EFCAB13 | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 117/365 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs761950286; called by muse, mutect2, varscan2
- FLG2 | c.4153C>T p.H1385Y | Missense Mutation (SNP) | VAF 202/455 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs749523871; called by muse, mutect2, varscan2
- FREM2 | c.9427G>A p.G3143R | Missense Mutation (SNP) | VAF 199/464 reads (43%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs1424371843; called by muse, mutect2, varscan2
- GIPC2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 134/323 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs138793126, COSV100883246; called by muse, mutect2, varscan2
- GPC6 | c.686G>A p.R229K | Missense Mutation (SNP) | VAF 112/221 reads (51%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.542); catalogued as rs748202641; called by muse, varscan2
- HNF4G | c.1072C>T p.P358S (on ENST00000354370 / NM_001330561.2; = p.P405S on NM_004133.5) | Missense Mutation (SNP) | VAF 114/231 reads (49%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs758119108, COSV62965774; called by muse, mutect2, varscan2
- KANK4 | c.1367G>A p.W456* | Nonsense Mutation (SNP) | VAF 182/415 reads (44%) | catalogued as rs1227438721; called by muse, mutect2, varscan2
- KIF15 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 137/339 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201923210; called by muse, mutect2, varscan2
- KMT2A | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 205/410 reads (50%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1224934712; called by muse, varscan2
- KRT85 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 250/597 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.14); catalogued as rs773634498, COSV57737355; called by muse, mutect2, varscan2
- MEGF8 | c.2341C>T p.R781W (on ENST00000251268 / NM_001271938.2; = p.R714W on NM_001410.3) | Missense Mutation (SNP) | VAF 228/531 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs745353025; called by muse, mutect2, varscan2
- MID1 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 335/1065 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as rs1407207268, COSV58195425; called by muse, mutect2, varscan2
- NLE1 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 162/520 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs761984655; called by muse, mutect2, varscan2
- NPAP1 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 203/474 reads (43%) | SIFT tolerated (0.91); PolyPhen benign (0.049); catalogued as COSV100275146; called by muse, mutect2, varscan2
- OPN4 | c.291-1G>A p.X97_splice | Splice Site (SNP) | VAF 99/212 reads (47%) | catalogued as rs766640490; called by muse, mutect2, varscan2
- PHGDH | c.1132C>T p.L378F | Missense Mutation (SNP) | VAF 160/383 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.162); catalogued as rs1047310984; called by muse, mutect2, varscan2
- PLEKHG1 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 142/467 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs1321828724; called by muse, mutect2, varscan2
- PYGO2 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 304/643 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs901394743; called by muse, mutect2, varscan2
- RAG2 | c.1524dup p.G509Rfs*15 | Frame Shift Ins (INS) | VAF 120/368 reads (33%) | catalogued as rs751978214; called by mutect2, pindel, varscan2
- RBMXL2 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 302/682 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as rs1406597062; called by muse, mutect2, varscan2
- SAFB2 | c.2192C>T p.P731L | Missense Mutation (SNP) | VAF 122/319 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs1451116429; called by muse, mutect2, varscan2
- SHANK1 | c.4612G>A p.E1538K | Missense Mutation (SNP) | VAF 227/569 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs370032906; called by muse, mutect2, varscan2
- SHROOM3 | c.3542G>A p.G1181E | Missense Mutation (SNP) | VAF 271/607 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1228408998; called by muse, mutect2, varscan2
- SOX3 | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 362/1235 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.336); catalogued as rs1556518165; called by muse, mutect2, varscan2
- TET3 | c.4421C>T p.S1474F | Missense Mutation (SNP) | VAF 210/511 reads (41%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.593); catalogued as rs1030846816, COSV69642799; called by muse, mutect2, varscan2
- USP17L10 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 32/826 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1395052468; called by muse, mutect2
- ZNF503 | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 374/848 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1045387043; called by muse, mutect2, varscan2
- ADGRG7 | c.2078A>G p.N693S | Missense Mutation (SNP) | VAF 107/259 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AGBL1 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 75/240 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMIGO2 | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 168/407 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ANK3 | c.6620C>T p.P2207L | Missense Mutation (SNP) | VAF 131/318 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ARHGEF18 | c.2168C>A p.S723* (on ENST00000359920 / NM_001130955.2; = p.S619* on NM_015318.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 113/296 reads (38%) | called by muse, mutect2, varscan2
- C11orf87 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 263/588 reads (45%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- CADPS | c.3193G>A p.E1065K | Missense Mutation (SNP) | VAF 137/342 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CFAP47 | c.1744G>A p.D582N | Missense Mutation (SNP) | VAF 185/594 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CHRNA5 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 67/160 reads (42%) | called by muse, mutect2, varscan2
- CLIC6 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 301/962 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- CNPY3 | c.498T>G p.C166W | Missense Mutation (SNP) | VAF 96/276 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COL4A2 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 163/396 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPS1 | c.4055C>T p.S1352F | Missense Mutation (SNP) | VAF 123/343 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CYB5R2 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 162/371 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DENND5A | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 164/359 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLGAP1 | c.2306C>T p.P769L | Missense Mutation (SNP) | VAF 192/638 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAH8 | c.1829G>C p.R610P | Missense Mutation (SNP) | VAF 81/326 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- EYS | c.6611T>G p.F2204C | Missense Mutation (SNP) | VAF 79/316 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- FAM181B | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 150/375 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- GLOD5 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 93/376 reads (25%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HCN3 | c.2222C>T p.P741L | Missense Mutation (SNP) | VAF 331/748 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRATD1 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 309/682 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- MAPK8IP3 | c.2309C>T p.S770F | Missense Mutation (SNP) | VAF 184/449 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- MGAM2 | c.6814C>T p.P2272S | Missense Mutation (SNP) | VAF 67/191 reads (35%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- NCR3 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 228/838 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NECTIN4 | c.128T>G p.V43G | Missense Mutation (SNP) | VAF 246/554 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRP3 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 166/355 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NPIPA1 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.251); called by mutect2, varscan2
- NWD2 | c.453G>C p.K151N | Missense Mutation (SNP) | VAF 201/450 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- OLFM3 | c.1064G>A p.G355E (on ENST00000338858 / NM_001288821.1; = p.G335E on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/275 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PPEF1 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 157/508 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- PRSS16 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 154/546 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- PTPN13 | c.2488-1G>A p.X830_splice | Splice Site (SNP) | VAF 87/203 reads (43%) | called by muse, mutect2, varscan2
- PTPRK | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 141/528 reads (27%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- SCNN1B | c.1646G>A p.W549* | Nonsense Mutation (SNP) | VAF 209/490 reads (43%) | called by muse, mutect2, varscan2
- SELENOP | c.534G>A p.T178= | Splice Region (SNP) | VAF 63/140 reads (45%) | called by muse, mutect2, varscan2
- SH3BP4 | c.1628C>T p.S543F | Missense Mutation (SNP) | VAF 155/383 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- SKOR2 | c.2908C>T p.P970S | Missense Mutation (SNP) | VAF 62/231 reads (27%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- SLC27A2 | c.1247G>A p.R416K | Missense Mutation (SNP) | VAF 82/223 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SSNA1 | c.3_4insGG p.T2_?1 | Frame Shift Ins (INS) | VAF 240/664 reads (36%) | called by mutect2, pindel, varscan2
- SYN3 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 145/361 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- TBR1 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 182/403 reads (45%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TEX13D | c.65A>C p.N22T | Missense Mutation (SNP) | VAF 141/466 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TIAM1 | c.4541C>T p.S1514F | Missense Mutation (SNP) | VAF 195/649 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- TMC2 | c.2287C>T p.P763S | Missense Mutation (SNP) | VAF 116/283 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- TMEM67 | c.2386G>A p.G796R | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM67 | c.2387G>A p.G796E | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TRPC5 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 273/928 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZP4 | c.973A>C p.K325Q | Missense Mutation (SNP) | VAF 109/246 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- AC099489.1 | c.9267C>T p.S3089= | Silent (SNP) | VAF 153/385 reads (40%) | called by muse, mutect2
- ADAM29 | c.1371G>A p.K457= | Silent (SNP) | VAF 163/347 reads (47%) | called by muse, mutect2, varscan2
- ADGB | c.135C>T p.F45= | Silent (SNP) | VAF 132/482 reads (27%) | called by muse, mutect2, varscan2
- ATP1A3 | c.345C>T p.F115= (on ENST00000545399 / NM_001256214.2; = p.F102= on NM_152296.5) | Silent (SNP) | VAF 179/417 reads (43%) | catalogued as COSV57489873; called by muse, mutect2, varscan2
- CBY2 | c.360G>A p.R120= | Silent (SNP) | VAF 191/464 reads (41%) | catalogued as COSV60118380; called by muse, mutect2, varscan2
- CTNNA2 | c.903G>A p.P301= | Silent (SNP) | VAF 190/409 reads (46%) | catalogued as rs925979374, COSV63587154; called by muse, mutect2, varscan2
- DNM2 | c.168C>T p.F56= | Silent (SNP) | VAF 154/384 reads (40%) | called by muse, mutect2, varscan2
- DSCAM | c.1917G>A p.G639= | Silent (SNP) | VAF 216/669 reads (32%) | called by muse, mutect2, varscan2
- EMD | c.114C>T p.I38= | Silent (SNP) | VAF 215/838 reads (26%) | called by muse, mutect2, varscan2
- ERN2 | c.1065C>T p.S355= | Silent (SNP) | VAF 129/312 reads (41%) | catalogued as rs201668250; called by muse, mutect2, varscan2
- EVX2 | c.156C>T p.R52= | Silent (SNP) | VAF 259/605 reads (43%) | catalogued as rs772267515; called by muse, mutect2, varscan2
- FREM2 | c.9426G>A p.R3142= | Silent (SNP) | VAF 199/462 reads (43%) | called by muse, mutect2, varscan2
- GBP2 | c.708C>T p.F236= | Silent (SNP) | VAF 136/345 reads (39%) | catalogued as rs1319474106, COSV100975432; called by muse, varscan2
- GLOD5 | c.72G>A p.R24= | Silent (SNP) | VAF 89/369 reads (24%) | catalogued as rs1309512340; called by muse, mutect2, varscan2
- HMCN1 | c.4143C>T p.F1381= | Silent (SNP) | VAF 129/301 reads (43%) | called by muse, mutect2, varscan2
- IGKV1OR2-108 | c.352_353del p.*118del | Silent (DEL) | VAF 84/118 reads (71%) | called by mutect2, pindel*, varscan2*
- IGLV1-44 | c.171G>A p.Q57= | Silent (SNP) | VAF 187/421 reads (44%) | catalogued as rs553836778; called by muse, mutect2, varscan2
- IKBKG | c.663G>A p.S221= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as rs1244513741; called by mutect2, varscan2
- IRF2BP1 | c.312C>T p.G104= | Silent (SNP) | VAF 305/724 reads (42%) | catalogued as rs550504759; called by muse, mutect2, varscan2
- KANK2 | c.447C>T p.T149= | Silent (SNP) | VAF 361/770 reads (47%) | called by muse, mutect2, varscan2
- KRTAP13-1 | c.417C>T p.S139= | Silent (SNP) | VAF 214/723 reads (30%) | catalogued as COSV62663339; called by muse, mutect2, varscan2
- L1CAM | c.2490G>A p.L830= | Silent (SNP) | VAF 242/738 reads (33%) | called by muse, mutect2, varscan2
- LRATD1 | c.672G>A p.R224= | Silent (SNP) | VAF 311/694 reads (45%) | catalogued as rs536808118; called by muse, mutect2, varscan2
- LRRIQ4 | c.546G>A p.Q182= | Silent (SNP) | VAF 220/471 reads (47%) | called by muse, mutect2, varscan2
- MYO18B | c.3747C>T p.I1249= | Silent (SNP) | VAF 163/346 reads (47%) | called by muse, mutect2, varscan2
- MYO1C | c.1527C>T p.F509= (on ENST00000648651 / NM_001080779.2; = p.F474= on NM_033375.5) | Silent (SNP) | VAF 153/570 reads (27%) | catalogued as COSV62999119; called by muse, mutect2, varscan2
- NKX2-8 | c.666C>T p.L222= | Silent (SNP) | VAF 277/619 reads (45%) | called by muse, varscan2
- NT5C1B | c.1776G>A p.G592= (on ENST00000359846 / NM_001199086.2; = p.G532= on NM_033253.4) | Silent (SNP) | VAF 172/399 reads (43%) | called by muse, mutect2, varscan2
- OR2F1 | c.543C>T p.L181= | Silent (SNP) | VAF 196/471 reads (42%) | catalogued as COSV67331014; called by muse, mutect2, varscan2
- PLXNB3 | c.4311G>A p.R1437= | Silent (SNP) | VAF 193/649 reads (30%) | called by muse, mutect2, varscan2
- PTPRK | c.606G>A p.G202= | Silent (SNP) | VAF 139/521 reads (27%) | catalogued as COSV100949616; called by muse, mutect2, varscan2
- ROBO3 | c.3441C>T p.S1147= | Silent (SNP) | VAF 227/513 reads (44%) | called by muse, mutect2, varscan2
- SAFB2 | c.2193C>T p.P731= | Silent (SNP) | VAF 122/317 reads (38%) | called by muse, mutect2, varscan2
- SH3D19 | c.45C>T p.R15= | Silent (SNP) | VAF 197/484 reads (41%) | called by muse, mutect2, varscan2
- SLC2A13 | c.1554C>T p.V518= | Silent (SNP) | VAF 71/211 reads (34%) | called by muse, mutect2, varscan2
- SMOC2 | c.837G>A p.P279= (on ENST00000356284 / NM_001166412.2; = p.P290= on NM_022138.3) | Silent (SNP) | VAF 250/705 reads (35%) | catalogued as rs376609544; called by muse, mutect2, varscan2
- SOX3 | c.756G>A p.V252= | Silent (SNP) | VAF 362/1231 reads (29%) | called by muse, mutect2, varscan2
- TCAIM | c.507C>T p.S169= | Silent (SNP) | VAF 134/297 reads (45%) | called by muse, mutect2, varscan2
- USP17L1 | c.495C>T p.L165= | Silent (SNP) | VAF 161/433 reads (37%) | called by muse, mutect2, varscan2
- DUSP22 | c.508+12G>A | Intron (SNP) | VAF 134/762 reads (18%) | catalogued as COSV60527759; called by muse, mutect2
- LAMA4 | c.297+2307G>A | Intron (SNP) | VAF 122/386 reads (32%) | catalogued as rs782484726, COSV54570476; called by muse, mutect2, varscan2
